Gene-level copy-number profile of tumor specimen TCGA-ZH-A8Y2-01A from TCGA case TCGA-ZH-A8Y2, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.5 years (21,743 days).
Specimen TCGA-ZH-A8Y2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.5031c071-bdf5-4c5e-b5f3-9ff7e906427b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZH-A8Y2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/184e4ec7-6887-45fc-9298-0cc4413e21e5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 2: 18,574; copy number 3: 11,070; copy number 4: 23,078; copy number 5: 5,737; copy number 6: 464; copy number 8: 112; copy number 9: 602; copy number 10: 113.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZH-A8Y2-01A-11D-A416-01): tumor purity 0.77, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–23,438,700, 70 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 715 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–5,140,119, 109 genes, copy number 9 (broad region; genes not listed).
- chr5:6,839,460–13,944,543, 119 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr5:17,684,584–45,895,970, 370 genes, copy number 9–10 (broad region; genes not listed).
- chr12:53,326,575–55,615,878, 117 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
